Gene-level copy-number profile of tumor specimen TCGA-2L-AAQE-01A from TCGA case TCGA-2L-AAQE, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 56.4 years (20,618 days).
Specimen TCGA-2L-AAQE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.0aa78318-c980-4c42-8afc-41cf3f92ac0e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2L-AAQE-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/835feb8a-c045-4187-beba-387f66f5a656

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4,157; copy number 1: 15,721; copy number 2: 38,499; copy number 3: 1,642; copy number 4: 111; copy number 5: 41; copy number 6: 99.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2L-AAQE-01A-11D-A396-01): tumor purity 0.38, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1,236 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:64,450,096–64,461,381, 2 genes (within-gene range 0–2): AC008074.1, LGALSL.
- chr9:1,977,784–29,826,711, 354 genes (broad region; genes not listed).
- chr9:35,161,992–38,543,880, 114 genes (within-gene range 0–2) (broad region; genes not listed).
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr18:25,953,216–80,247,514, 764 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 140 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:151,380,341–151,382,381, 1 gene, copy number 5 (within-gene range 2–5): AC034205.3.
- chr8:42,541,155–43,674,591, 40 genes, copy number 5 (within-gene range 3–5): SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr14:105,736,343–106,344,833, 99 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,701. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
